Somatic mutation profile of tumor specimen 0DODO1 from CCDI case PBCCLP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.9 years (2,144 days).
Specimen 0DODO1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a70570f1-579b-44bf-a06e-8a443fa018bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DODMC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f9f7f0-cfd6-4b24-916f-51c4af771d3f

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBRA1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs757353536; called by muse, mutect2, varscan2
- C4orf17 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373542741; called by muse, mutect2, varscan2
- CNOT3 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs949030155, COSV55366903; called by muse, mutect2
- KIFC3 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 124/210 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV65552406; called by muse, mutect2, varscan2
- ASIC2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPHN | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 132/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NDC80 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH3 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SASH1 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.293); called by muse, mutect2
- SORBS1 | c.1973T>C p.F658S (on ENST00000361941 / NM_001034954.2; = p.F364S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/134 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AFP | c.1512A>T p.S504= | Silent (SNP) | VAF 129/289 reads (45%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.921C>T p.N307= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs927866269, COSV100160504; called by muse, mutect2, varscan2
